Somatic mutation profile of tumor specimen TCGA-X8-AAAR-01A (aliquot TCGA-X8-AAAR-01A-11D-A403-09) from TCGA case TCGA-X8-AAAR, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G1; Age at diagnosis: 69.5 years (25,370 days).
Specimen TCGA-X8-AAAR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bc22ec6-2175-49ff-86a4-fe633865d6f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X8-AAAR-10A (Blood Derived Normal), aliquot TCGA-X8-AAAR-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbcafca1-3c0b-4435-b8b7-2fdcc8559f53

The open-access MAF lists 112 somatic variants for this specimen: 81 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 29, Frame Shift Ins 3, Splice Region 2, Splice Site 2, Nonsense Mutation 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PNLIPRP3 | c.1292A>C p.K431T | Missense Mutation (SNP) | VAF 54/163 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.2); PolyPhen benign (0.241); catalogued as COSV65046911, COSV65048763; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as rs1465496890, COSV55747946; called by muse, mutect2, varscan2
- ACTBL2 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.251); catalogued as rs772855283, COSV70661077; called by muse, mutect2, varscan2
- ADAMTS19 | c.2150T>G p.L717R | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.36); catalogued as COSV50732503; called by muse, mutect2, varscan2
- ADGRE1 | c.628T>G p.L210V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs1030710247; called by muse, mutect2, varscan2
- APCDD1L | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777635496; called by muse, mutect2, varscan2
- CCNA1 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.153); catalogued as rs267603812, COSV55220912; called by muse, mutect2, varscan2
- CD163 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as COSV100776065; called by muse, mutect2, varscan2
- CLEC3A | c.157C>A p.L53M (on ENST00000651443; = p.L44M on NM_005752.6) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs779933246; called by muse, mutect2, varscan2
- COL23A1 | c.468+1G>A p.X156_splice | Splice Site (SNP) | VAF 51/65 reads (78%) | catalogued as rs752804406, COSV66795195; called by muse, mutect2, varscan2
- CYLC1 | c.743T>A p.L248H | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV104412459, COSV61415841; called by muse, mutect2, varscan2
- DAB2IP | c.39C>T p.Y13= | Splice Region (SNP) | VAF 8/50 reads (16%) | catalogued as rs201252302, COSV52255139; called by muse, mutect2, varscan2
- DCAF12L1 | c.1307A>C p.Y436S | Missense Mutation (SNP) | VAF 45/60 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100948330, COSV64421363; called by muse, mutect2, varscan2
- DEPDC5 | c.3322G>A p.A1108T (on ENST00000400246; = p.A1177T on NM_014662.5) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.984); catalogued as rs748662185, COSV99836806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELF2 | c.344G>A p.R115K (on ENST00000379550 / NM_001331036.2; = p.R55K on NM_006874.4) | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV99642766; called by muse, mutect2, varscan2
- GLRB | c.1092A>C p.K364N | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.328); catalogued as COSV52413192, COSV52413785; called by muse, mutect2, varscan2
- GRIA3 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 94/125 reads (75%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.993); catalogued as rs747646413, COSV52079590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GTF3C5 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1317734001; called by muse, mutect2, varscan2
- IFI16 | c.349A>C p.T117P | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV55535402; called by muse, mutect2, varscan2
- KCNMB2 | c.656T>G p.L219R | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV64201354, COSV64201489; called by muse, mutect2, varscan2
- KRT31 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 75/96 reads (78%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as rs760386378, COSV52434745; called by muse, mutect2, varscan2
- LPIN3 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs926588748; called by muse, mutect2, varscan2
- LRRTM4 | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.277); catalogued as rs1396734599, COSV69138746, COSV69141749; called by muse, mutect2, varscan2
- LY75 | c.4696C>T p.H1566Y | Missense Mutation (SNP) | VAF 55/82 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1014742633, COSV55101942, COSV55104242; called by muse, mutect2, varscan2
- MUC16 | c.19823C>T p.S6608L | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs746016038, COSV67445814, COSV67466930; called by muse, mutect2, varscan2
- MYO15A | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.09); catalogued as COSV52759669; called by muse, mutect2, varscan2
- MYO16 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1291880607, COSV51798056; called by muse, mutect2, varscan2
- NRCAM | c.3716G>A p.R1239Q (on ENST00000379028 / NM_001371124.1; = p.R1118Q on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0.047); catalogued as rs753564364, COSV61048115; called by muse, mutect2, varscan2
- PABPC5 | c.110A>C p.K37T | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV57041654, COSV57041670; called by muse, mutect2, varscan2
- PBRM1 | c.1758G>T p.M586I | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV56270122, COSV56302342; called by muse, mutect2, varscan2
- PCDHA11 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 53/80 reads (66%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.014); catalogued as COSV100250425; called by muse, mutect2, varscan2
- PITPNM1 | c.1717G>A p.D573N | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1203045056; called by muse, mutect2, varscan2
- PLAC1 | c.355dup p.Q119Pfs*26 | Frame Shift Ins (INS) | VAF 13/36 reads (36%) | catalogued as rs755064750; called by mutect2, pindel, varscan2
- PRAMEF20 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1409989552; called by muse, mutect2, varscan2
- PXN | c.1295T>A p.L432H (on ENST00000228307 / NM_001080855.3; = p.L398H on NM_002859.4) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57220647; called by muse, mutect2, varscan2
- RGS6 | c.480G>C p.Q160H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV59593794; called by muse, mutect2, varscan2
- RUBCNL | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs753678651, COSV100528801; called by muse, mutect2, varscan2
- SEC24B | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1355964971; called by muse, mutect2, varscan2
- SLC44A5 | c.749C>T p.T250M | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.335); catalogued as rs576032462; called by muse, mutect2, varscan2
- SOGA3 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.207); catalogued as rs1409928892; called by muse, mutect2, varscan2
- SPATA2L | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs369296594; called by muse, mutect2, varscan2
- STRIP2 | c.2218C>T p.R740C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1221943301, COSV50804158, COSV99974241; called by muse, mutect2, varscan2
- SYNE1 | c.6554T>G p.L2185R (on ENST00000367255 / NM_182961.4; = p.L2192R on NM_033071.3) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV54905694; called by muse, mutect2, varscan2
- TMEM236 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs1564590552; called by muse, mutect2, varscan2
- TTN | c.8791G>T p.V2931L (on ENST00000591111; = p.V2885L on NM_003319.4) | Missense Mutation (SNP) | VAF 31/43 reads (72%) | PolyPhen possibly damaging (0.511); catalogued as rs756031984; called by muse, mutect2, varscan2
- ADAR | c.1534G>C p.A512P | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARCN1 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF25 | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CATSPERB | c.3026_3030dup p.P1011Ifs*8 | Frame Shift Ins (INS) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- CHRM2 | c.1043G>C p.G348A | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CSMD1 | c.7859T>G p.V2620G (on ENST00000520002; = p.V2619G on NM_033225.6) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CTR9 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- CTR9 | c.1598G>A p.C533Y | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DDX50 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- DSEL | c.1607T>C p.L536P | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERG | c.39+1G>A p.X13_splice | Splice Site (SNP) | VAF 21/70 reads (30%) | called by muse, mutect2, varscan2
- FBL | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- GGT7 | c.833A>G p.E278G | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- GHR | c.100T>C p.W34R | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSPB11 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- HTR7 | c.1138A>T p.N380Y | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IFFO1 | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- JAKMIP3 | c.909T>A p.S303R | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KLHL7 | c.694A>G p.K232E (on ENST00000339077 / NM_001031710.3; = p.K184E on NM_018846.5) | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.239); called by muse, mutect2
- LRP1B | c.4722dup p.F1575Ifs*9 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | called by mutect2, pindel
- NRIP1 | c.2284G>T p.D762Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- OR4C16 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- OR51L1 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- PPA2 | c.835C>T p.L279F (on ENST00000341695 / NM_176869.3; = p.L250F on NM_006903.4) | Missense Mutation (SNP) | VAF 110/363 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- PRAMEF17 | c.601A>G p.R201G | Missense Mutation (SNP) | VAF 124/294 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PRAMEF6 | c.1288A>G p.R430G | Missense Mutation (SNP) | VAF 71/448 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SCN7A | c.2219A>G p.E740G | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- SHPRH | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- TARBP1 | c.3063T>C p.I1021= | Splice Region (SNP) | VAF 24/99 reads (24%) | called by muse, mutect2, varscan2
- THSD7B | c.4373A>C p.N1458T (on ENST00000272643; = p.N1456T on NM_001316349.2) | Missense Mutation (SNP) | VAF 42/53 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- YBX1 | c.893A>T p.Q298L | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ZIC5 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ZNF106 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF320 | c.353A>C p.K118T | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF607 | c.1681T>C p.Y561H | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ABCC12 | c.3240G>A p.T1080= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV60911255; called by muse, mutect2, varscan2
- ALDH3B1 | c.900C>T p.C300= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as rs543365099; called by muse, mutect2, varscan2
- CCKBR | c.729C>A p.R243= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs202013673; called by muse, mutect2, varscan2
- CRTC1 | c.1350C>T p.S450= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs370433268; called by muse, mutect2, varscan2
- EHD3 | c.309A>G p.G103= | Silent (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- FIBCD1 | c.1299C>T p.D433= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs371058676; called by muse, mutect2, varscan2
- FMN2 | c.1299G>A p.P433= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV60425526; called by muse, mutect2, varscan2
- HS3ST1 | c.165G>A p.P55= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs767392229, COSV50023414; called by muse, mutect2, varscan2
- IGHV2-26 | c.177T>C p.R59= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as rs1555476580; called by muse, mutect2, varscan2
- KIAA1328 | c.1599C>T p.S533= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as rs749175808; called by muse, mutect2, varscan2
- KRTAP10-6 | c.507C>T p.S169= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- MRGPRX3 | c.213C>T p.A71= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs147032356, COSV66934522; called by muse, mutect2
- NAALAD2 | c.1107C>T p.D369= | Silent (SNP) | VAF 32/101 reads (32%) | called by muse, mutect2, varscan2
- NDST4 | c.1020A>G p.A340= | Silent (SNP) | VAF 33/99 reads (33%) | called by muse, mutect2, varscan2
- PCDHB6 | c.1731G>A p.A577= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV99169870; called by muse, mutect2, varscan2
- PCNT | c.2778G>A p.A926= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs149992133; called by muse, mutect2, varscan2
- PGBD5 | c.825C>A p.P275= (on ENST00000525115; = p.P344= on NM_001258311.2) | Silent (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- PLCL2 | c.2127G>C p.L709= (on ENST00000615277 / NM_001144382.2; = p.L583= on NM_015184.5) | Silent (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- POLE | c.3438C>A p.T1146= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- RYR2 | c.841A>C p.R281= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV63674295; called by muse, mutect2, varscan2
- SDK1 | c.672T>G p.T224= | Silent (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- SHANK3 | c.3348G>T p.A1116= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV53190938; called by muse, mutect2
- SLC26A9 | c.1848G>A p.P616= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs776579235; called by muse, varscan2
- SV2A | c.351G>A p.A117= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs200889129, COSV100975030; called by muse, varscan2
- TLK2 | c.2295G>A p.A765= (on ENST00000326270 / NM_001284333.2; = p.A743= on NM_006852.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs754947731; called by muse, mutect2, varscan2
- TNRC18 | c.3753C>T p.P1251= | Silent (SNP) | VAF 47/129 reads (36%) | catalogued as rs779371158, COSV68163387; called by muse, mutect2, varscan2
- TTN | c.6594T>G p.T2198= (on ENST00000591111; = p.T2152= on NM_003319.4) | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV100592265; called by muse, mutect2
- VWA2 | c.1773G>A p.R591= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs756311283, COSV100073990; called by muse, mutect2, varscan2
- ZNF790 | c.1062T>C p.T354= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV100764887; called by muse, mutect2, varscan2
- AC073310.1 | n.410T>C | RNA (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- RIMS2 | c.1692+169G>A | Intron (SNP) | VAF 17/54 reads (31%) | catalogued as rs753887468, COSV51682789; called by muse, mutect2, varscan2
